Somatic mutation profile of tumor specimen TCGA-06-0743-01A (aliquot TCGA-06-0743-01A-01D-1492-08) from TCGA case TCGA-06-0743, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,434 days).
Specimen TCGA-06-0743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad18002f-4246-4d34-b740-b78ddfc2621d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0743-10A (Blood Derived Normal), aliquot TCGA-06-0743-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/381258bf-7787-44fa-ae9c-a764e625d768

The open-access MAF lists 98 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 27, Nonsense Mutation 4, Frame Shift Del 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 426/1683 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.2387A>G p.Q796R | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1454697014, COSV61282328; called by muse, mutect2
- ADGRE2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs374318452; called by muse, mutect2, varscan2
- AGTR2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 93/124 reads (75%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as rs1309210708, COSV64156635; called by muse, mutect2, varscan2
- AOC1 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV62871244; called by muse, mutect2, varscan2
- AQP12A | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV61837822; called by muse, mutect2, varscan2
- ARHGEF16 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.227); catalogued as rs761054802, COSV65683429; called by muse, mutect2, varscan2
- CACNA2D4 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173208667, COSV54962310; called by muse, mutect2, varscan2
- CBFA2T3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs761802573, COSV51930622; called by muse, mutect2, varscan2
- CBY2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV60120080; called by muse, mutect2, varscan2
- CCBE1 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67949305, COSV67951745; called by muse, mutect2, varscan2
- CDH18 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56965713; called by muse, mutect2, varscan2
- CFAP65 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs772103989, COSV58562929; called by muse, mutect2, varscan2
- CNTN5 | c.2115C>A p.N705K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV54291528, COSV54362945; called by muse, mutect2, varscan2
- COL1A2 | c.3127G>C p.A1043P | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51967183; called by muse, mutect2, varscan2
- COL6A3 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756045079, COSV55095820; called by muse, mutect2, varscan2
- CRADD | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as COSV60557045; called by muse, mutect2, varscan2
- CSMD3 | c.2130G>A p.W710* (on ENST00000297405 / NM_001363185.1; = p.W606* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV52336895; called by muse, mutect2, varscan2
- CST1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs768059525, COSV59054750; called by muse, mutect2, varscan2
- DGKQ | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs752503518, COSV53281525; called by muse, mutect2
- FLG | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 208/575 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV64251028; called by muse, mutect2, varscan2
- FLG2 | c.6950A>C p.Q2317P | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.84); catalogued as COSV66174115; called by muse, mutect2, varscan2
- FLNA | c.3718G>A p.V1240M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61037442; called by muse, mutect2, varscan2
- GIMAP6 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV61032590; called by muse, mutect2, varscan2
- GLG1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as rs777605205, COSV52675420; called by muse, mutect2, varscan2
- IGKV1-16 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs768248545; called by muse, varscan2
- IL36B | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV52089406, COSV99382640; called by muse, mutect2, varscan2
- JCHAIN | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs1209409722, COSV54660150; called by muse, mutect2, varscan2
- KHDC3L | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1267639775, COSV64864200; called by muse, mutect2, varscan2
- KLHL5 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305397526, COSV54679234; called by muse, mutect2, varscan2
- KMT2D | c.8923C>T p.R2975C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs544530436, COSV56492192; called by muse, mutect2, varscan2
- LCE3E | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1398597048, COSV64232333; called by muse, mutect2, varscan2
- MACC1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.745); catalogued as COSV60546958; called by muse, mutect2, varscan2
- MAGEC3 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100025775, COSV71610265; called by muse, mutect2
- MAP3K1 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68122353; called by muse, mutect2, varscan2
- MAST2 | c.4288C>T p.L1430F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV63621668; called by muse, mutect2, varscan2
- MAX | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52420269; called by muse, mutect2, varscan2
- MYLIP | c.516A>C p.E172D | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV62767751; called by muse, mutect2, varscan2
- NAALADL2 | c.768C>G p.S256R | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV70296715; called by muse, mutect2, varscan2
- NMUR2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54920153; called by muse, mutect2, varscan2
- OR10H1 | c.945del p.N315Kfs*2 | Frame Shift Del (DEL) | VAF 34/171 reads (20%) | catalogued as rs770020662; called by mutect2, pindel, varscan2
- P2RX5 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs373920522; called by muse, mutect2, varscan2
- P2RY8 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV67178411; called by muse, mutect2, varscan2
- PAMR1 | c.1781C>T p.S594F (on ENST00000619888 / NM_001001991.3; = p.S611F on NM_015430.4) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs554767403, COSV53517080; called by muse, mutect2, varscan2
- PCDH11Y | c.3500G>T p.S1167I | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as COSV53093057; called by muse, mutect2, varscan2
- PCDHA7 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as COSV65342551; called by muse, mutect2, varscan2
- PER2 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV54528499; called by muse, mutect2, varscan2
- PEX12 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs988442642, COSV56777592; called by muse, mutect2, varscan2
- PGBD2 | c.1657T>A p.W553R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.795); catalogued as COSV61401304; called by muse, mutect2, varscan2
- PIAS3 | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV57908772; called by muse, mutect2, varscan2
- PLCD1 | c.1545G>T p.Q515H | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV52188397; called by muse, mutect2, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2, varscan2
- PTEN | c.999del p.N334Tfs*10 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as COSV64294287; called by mutect2, pindel, varscan2
- SCN10A | c.1909A>T p.S637C | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV71862779; called by muse, mutect2, varscan2
- SEL1L2 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as COSV53159110; called by muse, mutect2, varscan2
- SLC22A7 | c.577G>A p.V193I (on ENST00000372585 / NM_153320.2; = p.V191I on NM_006672.3) | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs750816224, COSV65354729, COSV65355654; called by muse, mutect2, varscan2
- SMC3 | c.1182G>T p.W394C | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62422712; called by muse, mutect2, varscan2
- SORCS1 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53910118; called by muse, mutect2, varscan2
- SPAG4 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs753644797, COSV65331211; called by muse, mutect2, varscan2
- STRN3 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV62582200; called by muse, mutect2, varscan2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- TRRAP | c.3479G>T p.G1160V | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62839842, COSV62855613; called by muse, mutect2, varscan2
- TTN | c.31084G>A p.V10362I (on ENST00000591111; = p.V9435I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | PolyPhen benign (0.273); catalogued as rs369932282; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- YEATS2 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59373118; called by muse, mutect2, varscan2
- ZMAT4 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52716712; called by muse, mutect2, varscan2
- ZNF124 | c.734G>A p.C245Y (on ENST00000543802 / NM_001297568.1; = p.C183Y on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs771285659, COSV61508075; called by muse, mutect2, varscan2
- AARS2 | c.2182del p.V728Cfs*33 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- HEYL | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PWWP3B | c.1194del p.F398Lfs*12 | Frame Shift Del (DEL) | VAF 10/13 reads (77%) | called by mutect2, varscan2
- AC008397.2 | c.1422C>T p.C474= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as rs564646126, COSV53210097; called by muse, mutect2, varscan2
- ADGRD1 | c.1119C>T p.T373= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as rs549833008, COSV55459309; called by muse, mutect2, varscan2
- CD5L | c.285T>C p.S95= | Silent (SNP) | VAF 32/372 reads (9%) | catalogued as rs1315156730, COSV63823311, COSV63823336; called by muse, mutect2
- CILP2 | c.600C>T p.S200= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52281079; called by muse, mutect2, varscan2
- DMBT1 | c.7149C>T p.D2383= (on ENST00000338354 / NM_001377530.1; = p.D1626= on NM_004406.3) | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs749231034, COSV57533611; called by muse, mutect2, varscan2
- ERG | c.384C>T p.N128= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs774580195, COSV55740214; called by muse, mutect2, varscan2
- FAM81B | c.414C>T p.D138= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs1169470179, COSV51987339; called by muse, mutect2, varscan2
- FOXR2 | c.318C>T p.N106= | Silent (SNP) | VAF 44/44 reads (100%) | catalogued as COSV59259416; called by muse, mutect2, varscan2
- GCDH | c.975A>T p.P325= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV53368814; called by muse, mutect2, varscan2
- IFRD1 | c.1209C>T p.P403= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV50045501; called by muse, mutect2, varscan2
- KMT2B | c.5469C>T p.D1823= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV55870653; called by muse, mutect2, varscan2
- KRT38 | c.1278C>T p.C426= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs749309611, COSV55847846; called by muse, mutect2, varscan2
- MEGF8 | c.6624C>T p.T2208= (on ENST00000251268 / NM_001271938.2; = p.T2141= on NM_001410.3) | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs368865740, COSV99239491; called by muse, mutect2, varscan2
- MEP1A | c.2211C>T p.I737= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as rs139598232; called by muse, mutect2, varscan2
- MUC5B | c.13086C>T p.T4362= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs769035980, COSV71592033, COSV71596275; called by muse, mutect2, varscan2
- NAIP | c.414C>T p.Y138= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as rs759032459, COSV52000721; called by muse, mutect2, varscan2
- NPTX2 | c.672G>A p.A224= | Silent (SNP) | VAF 146/559 reads (26%) | catalogued as rs200093714, COSV55717377; called by muse, mutect2, varscan2
- PIF1 | c.789C>T p.I263= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs1230948748, COSV51424917; called by muse, varscan2
- PRDM9 | c.897A>G p.R299= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV57014191; called by muse, mutect2, varscan2
- PTPRO | c.963C>T p.Y321= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs199991892, COSV55521963, COSV99841205; called by muse, mutect2, varscan2
- SHOC1 | c.2970C>T p.N990= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV59507738; called by muse, mutect2, varscan2
- SRXN1 | c.306C>T p.Y102= | Silent (SNP) | VAF 77/141 reads (55%) | catalogued as rs140166119; called by muse, mutect2, varscan2
- TIMD4 | c.999G>A p.A333= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs188217458, COSV50855068; called by muse, mutect2, varscan2
- UNC93B1 | c.840G>A p.P280= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57101277; called by muse, mutect2, varscan2
- VPS13B | c.4866C>T p.I1622= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs543837370, COSV100663815, COSV62159276; called by muse, mutect2, varscan2
- ZNF208 | c.2982T>A p.I994= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV68113499; called by muse, mutect2, varscan2
- ZNF813 | c.846G>A p.Q282= | Silent (SNP) | VAF 49/181 reads (27%) | catalogued as COSV67178321; called by muse, mutect2, varscan2
- TPK1 | c.613+17369G>A | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs10251258, COSV100765698; called by muse, varscan2
